Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040031-09A.2 (aliquot TARGET-15-SJMPAL040031-09A.2-01D) from TARGET case TARGET-15-SJMPAL040031, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,054 days).
Specimen TARGET-15-SJMPAL040031-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdfc9d2f-2621-42cb-a316-b6ac30d5be88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040031-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040031-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463f7fd9-d923-4743-a17b-26adaba61213

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/190 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- EML4 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV59304955; called by muse, mutect2
- LENG8 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.694); catalogued as COSV100457063; called by muse, mutect2
- NPIPB11 | c.3118A>C p.T1040P | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as rs191545623; called by muse, varscan2
- HEATR5B | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, varscan2
- MPG | c.477C>A p.Y159* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
